Surgical pathology report (de-identified scan), TCGA case TCGA-55-8505, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8505-01A (Primary Tumor).

[page 1 of 3]
*** Final Report ***

Clinical History

Right lower lobe lung non-small cell carcinoma

Specimen

- #1 2R mediastinal lymph node
- #2 4R mediastinal lymph node
- #3 Level 7 mediastinal lymph node
- #4 Right lower lobe wedge H/O renal mass, determine primary or secondary
- #5 Level 8 mediastinal lymph node
- #6 Level 9 mediastinal lymph node
- #7 Level 7 mediastinal lymph node
- #8 Level 10 mediastinal lymph node
- #9 Completion right lower lobe freeze for bronchial margins

Gross Examination

- #1 Received fresh Labeled 2R mediastinal lymph node is a 0.5 x 0.3 x 0.2 cm red, irregular soft tissue fragment, entirely submitted for frozen section in one cassette.
- #2 Received fresh labeled 4R mediastinal lymph node is a 1.1 x 0.6 x 0.3 cm aggregate of two irregular, red, soft tissue fragments, entirely submitted for frozen section in one cassette.
- #3 Received fresh labeled level 7 mediastinal lymph node is a 1.1 x 0.6 x 0.3 cm irregular red soft tissue fragment, entirely submitted for frozen section in one cassette. [REDACTED]
- #4 Received fresh labeled right lower lobe wedge, history of renal mass is a 27 gm, 10.2 x 3.1 x 3.4 cm wedge resection specimen with a 10.2 cm stapled edge and an area of previous incision, revealing a 1.6 x 1.3 x 1.1 cm firm, irregular, stellate-shaped tan mass present 1.2 cm from the stapled margin. The
-

[page 2 of 3]
[REDACTED]

mass is also 1.1 cm away from the pleura. A single section of the mass is submitted for frozen section in one cassette. Additional representative sections are submitted as per block summary. Block summary: "4A", "4B" normal lung tissue beneath staple line; "4C"- "4E" additional sections of mass.

[REDACTED]

#5 Labeled level 8 mediastinal lymph node are two fragments of gray-black material, in aggregate 0.7 x 0.5 x 0.4 cm. Completely submitted in a single cassette.

#6 Labeled level 9 lymph node are three fragments of yellow-gray material, ranging from 0.2-1.2 cm, in aggregate 1.2 x 1.0 x 0.5 cm. Sectioned and completely submitted in a single cassette.

#7 Labeled level 7 lymph node is a single fragment of gray-black material, 1.4 x 1.0 x 0.4 cm. Longitudinally bisected and completely submitted in a single cassette.

#8 Labeled level 10 lymph node is a single fragment of gray-black material, 0.6 x 0.5 x 0.3 cm. Bisected and completely submitted in a single cassette.

[REDACTED]

#9 Received fresh for frozen section labeled right lower lobe-freeze bronchial margin, is a 264.1 gram, 18.5 x 14.5 x 4.5 cm long lobectomy specimen. The pleura is purple and smooth and intact. The bronchial margin is tangentially frozen as one cassette. There are five black pigmented lobar lymph nodes, up to 0.6 cm in greatest dimension. Sectioning demonstrates dark red-purple, soft parenchyma without masses, nodules or other gross abnormalities. Twelve sections are submitted in five: "A"- "E". Block Summary: "A", "B", vascular margins, tangential; "C", lobar lymph nodes; "D", central parenchyma; "E", peripheral parenchyma with pleura. [REDACTED]

Frozen Section Diagnosis

- #1 MEDIASTINAL LYMPH NODE 2R (1 FS): NO TUMOR SEEN. [REDACTED]
- #2 MEDIASTINAL LYMPH NODE 4R (1 FS): NO TUMOR SEEN. [REDACTED]
- #3 MEDIASTINAL LYMPH NODE LEVEL 7 (1 FS): NO TUMOR SEEN. [REDACTED]
- #9 LUNG, RIGHT LOWER LOBE, COMPLETION LOBECTOMY (1 FS): BRONCHIAL MARGIN NEGATIVE. [REDACTED]
- [REDACTED]
- [REDACTED]
- [REDACTED]

[page 3 of 3]
Microscopic Examination

#1-#9 Microscopic examination performed.

Comment

Selected slides reviewed in conjunction with Dr. [REDACTED]

Signature Line

Final Diagnosis

- #1 MEDIASTINAL LYMPH NODE, 2R: NEGATIVE FOR METASTATIC CARCINOMA.
#2 MEDIASTINAL LYMPH NODE, 4R: NEGATIVE FOR METASTATIC CARCINOMA.
#3 MEDIASTINAL LYMPH NODE, LEVEL 7: NEGATIVE FOR METASTATIC CARCINOMA.
#4 LUNG, RIGHT LOWER LOBE, WEDGE BIOPSY: INVASIVE ADENOCARCINOMA, MODERATELY DIFFERENTIATED.
TUMOR SIZE: 1.6 X 1.3 X 1.1 CM.
PLEURAL SURFACE STATUS: VISCERA PLEURA, NEGATIVE FOR CARCINOMA.
DIRECT EXTENSION OF TUMOR: NONE IDENTIFIED.
LYMPHOVASCULAR SPACE STATUS: NEGATIVE FOR LYMPHOVASCULAR SPACE INVASION.
PATHOLOGIC STAGE (TNM CLASSIFICATION): pT1a pN2 (SEE SPECIMEN #7).
#5 MEDIASTINAL LYMPH NODE, LEVEL 8: NEGATIVE FOR METASTATIC CARCINOMA.
#6 MEDIASTINAL LYMPH NODE, LEVEL 9: NEGATIVE FOR METASTATIC CARCINOMA.
#7 MEDIASTINAL LYMPH NODE, LEVEL 7: ONE LYMPH NODE, POSITIVE FOR METASTATIC CARCINOMA (1/1).
SIZE OF METASTASIS: 0.2 CM.
STATUS OF EXTRACAPSULAR TISSUE: NEGATIVE FOR EXTRACAPSULAR EXTENSION.
#8 MEDIASTINAL LYMPH NODE, LEVEL 10: NEGATIVE FOR METASTATIC CARCINOMA.
#9 LUNG, RIGHT LOWER LOBE, COMPLETION LOBECTOMY: NO RESIDUAL ADENOCARCINOMA IDENTIFIED.
BRONCHIAL MARGIN NEGATIVE.
MULTIPLE PERIBRONCHIAL LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA.

Ordering Provider

Ordering Physician: [REDACTED]

Source: NCI Genomic Data Commons file d9a6a4c0-e00c-4f79-93c7-b7b12d9b43a4 (TCGA-55-8505.401F1ED0-5DA9-442F-AC17-6394E72E88AE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).